Surgical pathology report (de-identified scan), TCGA case TCGA-44-2666, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-2666-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Posterior segment right upper lobe
- B. 2R fat pad
- C. 4R fat pad
- D. Level 7 lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right lung mass.

Diagnosed stage
I nonsmall cell carcinoma right upper lobe.
POST-OP DIAGNOSIS: Right lung mass.

GROSS DESCRIPTION

A. Received fresh labeled "posterior segment right upper lobe" is a 192 gram, 12.5 x 8.0 x 4.5 cm. portion of lung tissue with a 12 cm. staple line along one aspect. The pleura is dusky tan pink-purple with focal bullous formation. The staple line is removed and the underlying soft tissue margin is inked orange.

On the opposing aspect of the specimen is a focal area of pleural retraction with subjacent induration in keeping with tumor. The overlying pleura surface is inked blue and the specimen is sectioned. There is a moderately well circumscribed, 4.5 x 3.8 x 2.7 cm. rubbery tan white lesion which approaches the pleural surface to within less than 0.1 cm. A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The remaining parenchyma is spongiform tan red-purple with focal crepitation. No additional mass lesion or abnormality is identified. Representative sections are submitted in 8 blocks as labeled. RS8.

BLOCK SUMMARY: 1-3 - Tumor to inked pleural surface; 4 - tumor to normal parenchyma; 5 and 6 - staple line; 7 and 8 - random from remainder of specimen documenting bullae.

GROSS DESCRIPTION

B. Received fresh labeled "2R fat pad" are three slightly fragmented soft golden yellow to gray black tissues ranging from 0.35 to 1.4 cm. in greatest dimension. The specimens are submitted in toto in one block. AS1.

C. Received fresh labeled "4R fat pad" are four soft tan gray-red tissues averaging 0.3 cm. in greatest dimension which are submitted in toto. AS1.

D. Received fresh labeled "level 7 lymph node" are four fragmented soft gray black tissues ranging from 0.2 to 1.0 cm. in greatest dimension. The specimens are submitted in toto in one block. AS1.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma.
Histologic grade: Moderately differentiated.
Primary tumor (pT): Tumor is 4.5 cm in greatest dimension (pT2a).
Margins of resection: The stapled resection margin is negative for tumor.
Direct extension of tumor: There is fibrosis and inflammation in the pleural tissue adjacent to the tumor, but no extension of tumor into pleura is identified. Elastic stains were evaluated.
Venous (large vessel) invasion: Not identified.
Arterial (large vessel) invasion: Not identified.
Lymphatic (small vessel) invasion: Not identified.
Regional lymph nodes (pN): Specimens E, C and D regional lymph nodes negative for metastatic tumor (pN0).
Distant metastasis (pM): Not evaluated, pMX.
Other findings: Emphysematous blebs with focal areas of hemorrhage and prominent pigmented macrophages within expanded alveolar spaces consistent with prominent hemosiderin deposition. No infectious

MICROSCOPIC DESCRIPTION

organisms are identified via AFB and GMS stains evaluated on tissue block A6.

5x1, 3x3, 18x1, 17x2

This case was signed out at the

DIAGNOSIS

- A. Lung, right upper lobe posterior segment, resection:
- Invasive moderately differentiated adenocarcinoma, tumor size 4.5 cm (pT2a).
- Associated pleural scar, but no pleural infiltration identified.
- Emphysematous blebs and intraalveolar histiocytes with hemosiderin.
- No infectious organisms identified.
- B. Lymph nodes, 2R fat pad, biopsy:
- Negative for malignancy.
- C. Lymph node, 4R fat pad, biopsy:
- Negative for malignancy.
- D. Lymph node, level 7, biopsy:
- Negative for malignancy.
-

Source: NCI Genomic Data Commons file 8fad9171-fd3a-448b-9cb3-60d280025e52 (TCGA-44-2666.BBC3C899-16AF-41E4-9BA5-57963305DF6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).